Gene-level copy-number profile of tumor specimen TCGA-RD-A8N6-01A from TCGA case TCGA-RD-A8N6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 78.9 years (28,834 days).
Specimen TCGA-RD-A8N6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.fa259017-67fc-4ac9-8e4f-4d8eca45c794.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A8N6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0736c910-7c29-4002-86d0-e800f2d4286a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,090; copy number 2: 6,784; copy number 3: 24,884; copy number 4: 18,816; copy number 5: 3,622; copy number 6: 2,112; copy number 7: 1,348; copy number 8: 700; copy number 10: 185; copy number 12: 108; copy number 13: 8; copy number 21: 67; copy number 22: 1; copy number 30: 57; copy number 35: 2; copy number 69: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A8N6-01A-11D-A363-01): tumor purity 0.6, ploidy 3.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,509 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,336,446–62,224,731, 56 genes, copy number 8–13: MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192.
- chr5:58,198–45,895,970, 710 genes, copy number 7–8 (broad region; genes not listed).
- chr7:91,940,862–93,574,730, 33 genes, copy number 69 (within-gene range 4–69): AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489.
- chr11:45,647,689–47,191,542, 52 genes, copy number 10: CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1.
- chr11:98,676,391–101,209,591, 13 genes, copy number 7–35: AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1.
- chr12:2,440,189–2,941,138, 22 genes, copy number 8 (within-gene range 5–8): AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1.
- chr12:30,926,428–32,646,050, 58 genes, copy number 7–8 (within-gene range 4–8): TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr12:38,150,050–41,774,671, 44 genes, copy number 7: AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400.
- chr15:86,078,809–101,933,350, 361 genes, copy number 10–30 (broad region; genes not listed).
- chr20:15,892,355–64,313,132, 1,160 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 55. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
